Surgical pathology report (de-identified scan), TCGA case TCGA-29-1703, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1703-01A (Primary Tumor).

[page 1 of 5]
TCGA-29-1703

CLINICAL HISTORY:

Pelvic mass, abdominal/pelvic swell NOS. Omental caking with bilateral adnexal masses. Post menopausal

GROSS EXAMINATION:

A. "Omentum (AF1)", received fresh for frozen section. A 320.0 gram, 15.5 x 11.5 x 2.5 cm portion of tan-yellow, firm fibroadipose tissue with diffuse adhesions and white-tan adherent exudate is received. The specimen is serially sectioned to exhibit a tan-yellow, firm, cut surface throughout, i.e. tumor size greater than 2 cm. A representative section has been previously frozen as AF1 and the frozen section remnant is entirely submitted in block A1. An additional representative section is submitted in block A2.

B. "Right tube and ovary", received fresh and placed in formalin. A 101.0 gram, 8.0 x 5.8 x 3.7 cm ovary with an adherent 5.5 cm long fimbriated fallopian tube. The surface of the ovary is focally disrupted and is serially sectioned to exhibit a 4.5 x 3.8 x 2.8 cm thin walled cyst filled with a yellow-tan, waxy, sebaceous material, and a small amount of white-tan mucinous material. A 2.2 x 1.4 x 1.2 cm tan, friable nodule is attached to the cyst wall. No additional masses or papillary excrescences are grossly identified. The remainder of the parenchyma is replaced by a white-tan, firm tissue and multiple thin walled cysts up to 2.0 cm, one of which is lined by papillary excrescences.

BLOCK SUMMARY:

B1- mass adjacent to sebaceous-filled cyst
B2- cyst with papillary excrescences
B3- representative section of adherent fallopian tube
B4- representative section of friable nodule

C. "Anterior cul-de-sac", received fresh and placed in formalin. Received is a 3.8 x 2.0 x 0.8 cm aggregate of multiple fragments of tan-yellow fibroadipose tissue, representative of which are submitted in block C1.

D. "Left tube and ovary", received fresh and placed in formalin. A 50.0 gram, 6.5 x 5.0 x 2.2 cm ovary with an attached and focally embedded fimbriated fallopian tube is received. The surface of the ovary is disrupted and rough with multiple adhesions. The ovary is serially sectioned to exhibit a firm, white-tan cut surface with multiple cysts up to 2.2 cm in greatest dimension, one of which is lined by papillary excrescences. No normal ovarian tissue is grossly identified. The fallopian tube is 5.2 cm long with an average diameter of 0.4 cm.

BLOCK SUMMARY:

D1- cyst with papillary excrescences
D2- representative section of white-tan solid tissue
D3- representative section of embedded fallopian tube

E. "Uterus and cervix", received fresh and placed in formalin. Received is a 56.0 gram, 8.5 x 5.0 x 3.5 cm uterus with attached cervix. The serosa is covered with multiple adhesions and multiple, firm, white-tan adherent nodules. The white-tan, smooth and glistening ectocervix has a 0.7 cm patent os which opens into a 2.0 cm long tan, trabeculated endocervical canal. The 3.4 x 1.5 cm endometrial cavity is lined by a tan, smooth endometrium. The 0.1 cm endometrium overlies a 1.3 cm myometrium remarkable for a 1.3 cm in greatest dimension, white, well-circumscribed, whorled nodule with a bulging

[page 2 of 5]
cut surface. Representative sections of cervix are submitted in Block E1-2 and representative sections of endomyometrium are submitted in blocks E3-4.

F. "Left cul-de-sac", received fresh and placed in formalin. Received is a 5.2 x 4.5 x 1.6 cm fragment of tan-yellow fibroadipose tissue which is focally indurated. Sectioning reveals a white-tan, firm cut surface with yellow, lobulated adipose tissue. A representative section is submitted in Block F1.

G. "Rectosigmoid colon", received fresh and placed in formalin. Received is a 16.0 cm long unoriented segment of large intestine that ranges in circumference from 2.5 cm up to 5.5 cm. The serosa is diffusely covered with adhesions and multiple focal areas of induration. The lumen is focally stenotic and surrounded by indurated, yellow, lobulated adipose tissue. The mucosa is pink-tan and grossly unremarkable. Sectioning exhibits areas of white-tan, firm tissue deep to the mucosa, which corresponds to the areas of induration on the serosa.

BLOCK SUMMARY:

G1- stapled margin
G2- open margin
G3-4- representative sections of mucosa in relation to white-tan, firm tissue

TCGA-29-1703

H. "Posterior wall of bladder", received fresh and placed in formalin. Received is a 2.7 x 2.7 x 0.7 cm aggregate of multiple fragments of gray-tan tissue which is entirely submitted in block H1.

I. "Left pelvic side wall", received fresh and placed in formalin. Received is a 4.5 x 2.5 x 1.0 cm fragment of firm, tan-yellow fibroadipose tissue which is sectioned to exhibit a white-tan, firm cut surface with a minimal amount of yellow, lobulated adipose tissue. A representative section is submitted in Block I1.

J. "Small bowel nodules", received fresh and placed in formalin. Received is a 2.0 x 1.0 x 0.4 cm aggregate of multiple fragments of firm, gray-tan tissue which is entirely submitted in block J1.

K. "Omentum", received fresh and placed in formalin. Received is a 5.0 x 3.5 x 1.5 cm aggregate of two fragments of tan-yellow fibroadipose tissue with focal adhesions. Sectioning exhibits a white-tan, firm cut surface with a small amount of fibroadipose tissue. A representative section is submitted in block K1.

L. "Supragastric nodule", received fresh and placed in formalin. Received is a 3.5 x 2.3 x 0.9 cm fragment of tan-yellow fibroadipose tissue. Sectioning exhibits a white-tan, firm cut surface with a small amount of fibroadipose tissue. A representative section is submitted in block L1.

M. "Transverse colon nodule", received fresh and placed in formalin. Received is a 1.5 x 0.8 x 0.6 cm fragment of tan-gray tissue, which is sectioned and submitted entirely in block M1.

N. "Left high pericolic gutter", received fresh and placed in formalin. Received is a 3.3 x 3.0 x 1.1 cm fragment of tan-gray, firm fibroadipose tissue. Sectioning exhibits a white-tan, firm cut surface with a small amount of fibroadipose tissue. A representative section is submitted in block N1.

O. "Colon", received fresh and placed in formalin. Received is a 3.0 x 0.5 x 0.5 cm fragment of tan-gray tissue with a 3.0 cm long stapled line. The stapled line is removed and the remaining soft tissue is entirely submitted in block O1.

P. "Proximal donut", received fresh and placed in formalin. Received is a 1.2 cm annular fragment of gray-tan tissue with a 0.5 cm in diameter central defect which is bisected and entirely submitted in block P1.

[page 3 of 5]
Q. "Distal donut", received fresh and placed in formalin. Received is a 1.2 x 1.2 x 1.0 cm fragment of gray-tan tissue with a tan, glistening mucosa which is remarkable for a 0.5 cm in diameter defect. The specimen is bisected and entirely submitted in block Q1.

[REDACTED]

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AFI- adenocarcinoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Hysterectomy, bilateral salpingo-oophorectomy, omentectomy, partial colectomy, multiple biopsies.

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] as required for accreditation by the [REDACTED]. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

SUMMARY DIAGNOSIS: SEROUS ADENOCARCINOMA OF THE RIGHT AND LEFT OVARIES, INVOLVING BILATERAL FALLOPIAN TUBES, UTERINE SEROSA, OMENTUM, RECTOSIGMOID COLON, AND MULTIPLE ADDITIONAL PERITONEAL SITES AS LISTED BELOW.

DETAILED DIAGNOSES BY SITE:

A. "OMENTUM" (OMENTECTOMY):

METASTATIC SEROUS ADENOCARCINOMA.
TUMOR SIZE: GREATER THAN 2 CM.

[REDACTED] TCGA-29-1703

B. "RIGHT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

MODERATELY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA OF THE OVARY.
TUMOR SIZE: 8 CM.
FIGO GRADE: 2 OF 3.
SURFACE INVOLVEMENT: PRESENT.
REMAINDER OF OVARY WITH MATURE CYSTIC TERATOMA (4.5 CM), SEE COMMENT.
FALLOPIAN TUBE: POSITIVE FOR SEROUS CARCINOMA.

COMMENT: Adjacent to the tumor in the ovary is a mature cystic teratoma (dermoid cyst). The epithelium in the dermoid is unremarkable and there is no evidence that the carcinoma arose from the dermoid.

C. "ANTERIOR CUL-DE-SAC" (BIOPSY):

SEROUS ADENOCARCINOMA.

D. "LEFT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

MODERATELY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA OF THE OVARY.
TUMOR SIZE: 6.5 CM.
FIGO GRADE: 2 OF 3.

[REDACTED]

[page 4 of 5]
SURFACE INVOLVEMENT: PRESENT.
FALLOPIAN TUBE: POSITIVE FOR SEROUS CARCINOMA.

E. "UTERUS AND CERVIX" (HYSTERECTOMY):

UTERUS WITH SEROSAL IMPLANTS OF SEROUS ADENOCARCINOMA.
ENDOMETRIUM: NO PATHOLOGIC DIAGNOSIS.
MYOMETRIUM: LEIOMYOMA
CERVIX: NO PATHOLOGIC DIAGNOSIS.

F. "LEFT CUL-DE-SAC" (BIOPSY):

SEROUS ADENOCARCINOMA.

G. "RECTOSIGMOID COLON" (RESECTION):

SEGMENT OF COLON WITH EXTENSIVE INVOLVEMENT BY SEROUS ADENOCARCINOMA.

H. "POSTERIOR WALL OF BLADDER" (BIOPSY):

SEROUS ADENOCARCINOMA.

I. "LEFT PELVIC SIDEWALL" (BIOPSY):

SEROUS ADENOCARCINOMA.

TCGA-29-1703

J. "SMALL BOWEL NODULES" (BIOPSY):

SEROUS ADENOCARCINOMA.

K. "OMENTUM" (OMENTECTOMY):

SEROUS ADENOCARCINOMA.

L. "SUPRAGASTRIC NODULE" (BIOPSY):

SEROUS ADENOCARCINOMA.

M. "TRANSVERSE COLON NODULE" (BIOPSY):

SEROUS ADENOCARCINOMA.

N. "LEFT HIGH PERICOLIC GUTTER" (BIOPSY):

SEROUS ADENOCARCINOMA.

O. "COLON" (EXCISION):

COLON WITH ACUTE SEROSITIS.
NEGATIVE FOR MALIGNANCY.

P. "PROXIMAL DONUT" (EXCISION):

COLON WITH ACUTE AND ORGANIZING SEROSITIS.
NEGATIVE FOR MALIGNANCY.

[page 5 of 5]
Q. "DISTAL DONUT" (EXCISION):

COLON WITH ACUTE AND ORGANIZING SEROSITIS.
NEGATIVE FOR MALIGNANCY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED] TCGA-29-1703

[REDACTED]

Source: NCI Genomic Data Commons file e35a3ba5-a0f9-40aa-88cd-6651b862a4e6 (TCGA-29-1703.C8397AF0-67D2-4E69-993B-7349657E9953.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).